Somatic mutation profile of tumor specimen 0DIY6E from CCDI case PBBWCP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,570 days).
Specimen 0DIY6E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de08a1a4-3c00-499e-bd6b-9834ab433fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIY5Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10ca2a72-3d1e-40f5-8437-902224ca0493

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Intron 5, 3'UTR 2, Translation Start Site 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 240/608 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 188/766 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 240/569 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSDE1 | c.2020C>T p.R674C (on ENST00000358528 / NM_001007553.3; = p.R643C on NM_007158.6) | Missense Mutation (SNP) | VAF 64/909 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54755442; called by muse, mutect2
- DDX3X | c.668C>T p.A223V (on ENST00000399959; = p.A224V on NM_001356.5) | Missense Mutation (SNP) | VAF 30/419 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67863799; called by muse, mutect2
- EPHA5 | c.2587A>T p.S863C | Missense Mutation (SNP) | VAF 146/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56640873; called by muse, mutect2, varscan2
- MYPN | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as rs200352249; ClinVar: uncertain significance; called by muse, mutect2
- PPP4C | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 31/634 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54222859; called by muse, mutect2
- RPL5 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 25/548 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as CM108636; called by muse, mutect2
- SEMA3A | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 131/535 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs318240753, CM127987, COSV54862815; ClinVar: not provided; called by muse, mutect2, varscan2
- SETD2 | c.6325C>T p.R2109* | Nonsense Mutation (SNP) | VAF 46/701 reads (7%) | catalogued as COSV57430221; called by muse, mutect2
- SF3B4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 89/714 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV99641162; called by muse, mutect2, varscan2
- SHROOM3 | c.2861C>T p.S954L | Missense Mutation (SNP) | VAF 160/468 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs748368762; called by muse, mutect2, varscan2
- TRRAP | c.2534G>T p.G845V | Missense Mutation (SNP) | VAF 78/744 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62843644, COSV62854837; called by muse, mutect2, varscan2
- ATP6V1C1 | c.287-1G>C p.X96_splice | Splice Site (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- CDCP2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 50/580 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.027); called by muse, mutect2
- CLTRN | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 78/846 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRACD | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 51/975 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CREBBP | c.50_51del p.L17Qfs*9 | Frame Shift Del (DEL) | VAF 207/530 reads (39%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.2225T>C p.M742T | Missense Mutation (SNP) | VAF 26/784 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- TMEM116 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 40/648 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ZNF316 | c.2507G>A p.C836Y | Missense Mutation (SNP) | VAF 63/534 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- AQP1 | c.357G>T p.L119= | Silent (SNP) | VAF 233/779 reads (30%) | called by muse, mutect2, varscan2
- ARX | c.456C>T p.A152= | Silent (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- CNTNAP4 | c.675A>G p.E225= | Silent (SNP) | VAF 31/708 reads (4%) | called by muse, mutect2
- CPEB1 | c.426G>A p.A142= (on ENST00000617958; = p.A82= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/700 reads (3%) | catalogued as rs749124573, COSV55618148; called by muse, mutect2
- DUOX1 | c.4152G>A p.V1384= | Silent (SNP) | VAF 173/506 reads (34%) | called by muse, mutect2, varscan2
- SORCS2 | c.1425C>T p.R475= | Silent (SNP) | VAF 48/890 reads (5%) | catalogued as rs376549941; called by muse, mutect2
- UNC79 | c.7785G>C p.P2595= (on ENST00000393151 / NM_001346218.2; = p.P2418= on NM_020818.5) | Silent (SNP) | VAF 24/604 reads (4%) | catalogued as COSV56381050; called by muse, mutect2
- FBH1 | c.*49C>T | 3'UTR (SNP) | VAF 12/276 reads (4%) | catalogued as rs1023881889, COSV62984728; called by muse, mutect2
- FDFT1 | c.100-164G>T | Intron (SNP) | VAF 26/732 reads (4%) | called by muse, mutect2
- HSF4 | c.486-95G>A | Intron (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- MED13L | c.6501-79A>C | Intron (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- PHKB | c.*26G>A | 3'UTR (SNP) | VAF 150/440 reads (34%) | catalogued as COSV100067132; called by muse, mutect2, varscan2
- SHMT2 | c.312-54G>A | Intron (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- SZT2 | c.4308+74C>T | Intron (SNP) | VAF 10/262 reads (4%) | catalogued as rs906239117; called by muse, mutect2
